Somatic mutation profile of tumor specimen MMRF_2059_1_BM_CD138pos (aliquot MMRF_2059_1_BM_CD138pos_T1_KHS5U_L08126) from MMRF case MMRF_2059, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 57.2 years (20,887 days).
Specimen MMRF_2059_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8b998b6e-0501-4d18-a0e2-870ded719a94.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2059_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2059_1_PB_Whole_C2_KHS5U_L08127; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6d5226d4-9b6a-4792-933e-1494746244d4

The open-access MAF lists 288 somatic variants for this specimen: 110 protein-altering or splice-affecting, 28 silent, 150 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 91, 3'UTR 73, Intron 29, Silent 28, 5'UTR 17, 5'Flank 15, 3'Flank 10, RNA 5, Frame Shift Del 5, Nonsense Mutation 5, Splice Site 4, Frame Shift Ins 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AGXT | c.33dup p.K12Qfs*156 | Frame Shift Ins (INS) | VAF 34/88 reads (39%) | catalogued as rs180177201; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- ABCA1 | c.4156G>A p.E1386K | Missense Mutation (SNP) | VAF 56/115 reads (49%) | SIFT tolerated (0.43); PolyPhen benign (0.227); catalogued as rs755216595, COSV66071433; called by muse, mutect2, varscan2
- ABCA13 | c.15105G>T p.E5035D | Missense Mutation (SNP) | VAF 210/468 reads (45%) | SIFT tolerated (0.12); PolyPhen benign (0.413); catalogued as COSV68947011; called by muse, varscan2
- ABHD10 | c.61G>C p.A21P | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as COSV99845149; called by muse, mutect2, varscan2
- ACTB | c.252A>T p.K84N | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.119); catalogued as COSV59320657; called by muse, mutect2, varscan2
- ACTB | c.13A>T p.I5F | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.04); catalogued as COSV59318217; called by muse, varscan2
- ACTG1 | c.145C>T p.Q49* | Nonsense Mutation (SNP) | VAF 174/336 reads (52%) | catalogued as COSV59509557; called by muse, mutect2, varscan2
- ADCY7 | c.3062G>A p.R1021Q | Missense Mutation (SNP) | VAF 36/37 reads (97%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1157728842, COSV54268631; called by muse, mutect2, varscan2
- ALDH3B1 | c.292G>A p.A98T | Missense Mutation (SNP) | VAF 33/73 reads (45%) | SIFT tolerated (0.12); PolyPhen benign (0.292); catalogued as rs1272315452; called by muse, mutect2, varscan2
- ARSD | c.1759G>A p.E587K | Missense Mutation (SNP) | VAF 165/174 reads (95%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV66973320; called by muse, mutect2, varscan2
- AXL | c.983C>T p.T328M | Missense Mutation (SNP) | VAF 41/80 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs376355256, COSV56565971; called by muse, mutect2, varscan2
- C19orf47 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 65/172 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs758014713, COSV62924992; called by muse, mutect2, varscan2
- CADPS | c.2332C>T p.R778C | Missense Mutation (SNP) | VAF 138/259 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as rs774579772, COSV51870456, COSV99337363; called by muse, mutect2, varscan2
- CERS3 | c.160C>T p.R54C | Missense Mutation (SNP) | VAF 67/153 reads (44%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs767959919; called by muse, mutect2, varscan2
- CIT | c.3943G>A p.A1315T | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (0.18); PolyPhen benign (0.01); catalogued as rs374303430, COSV99948159; called by muse, mutect2, varscan2
- COL6A3 | c.7832C>T p.A2611V | Missense Mutation (SNP) | VAF 38/84 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs114806654, COSV55080355, COSV55089770, COSV55094724; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CRB1 | c.1942A>C p.I648L | Missense Mutation (SNP) | VAF 112/319 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as COSV66334289; called by muse, mutect2, varscan2
- CYBB | c.929T>C p.L310P | Missense Mutation (SNP) | VAF 53/54 reads (98%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM106192; called by muse, mutect2, varscan2
- DOCK6 | c.2392+7G>A | Splice Region (SNP) | VAF 16/45 reads (36%) | catalogued as rs1315088703; called by muse, mutect2, varscan2
- DTX1 | c.74T>A p.V25E | Missense Mutation (SNP) | VAF 39/65 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57499173; called by muse, mutect2, varscan2
- ELN | c.230C>A p.A77E | Missense Mutation (SNP) | VAF 20/165 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.624); catalogued as rs1554668330, COSV52711018; called by muse, mutect2, varscan2
- FABP9 | c.388G>A p.E130K | Missense Mutation (SNP) | VAF 142/334 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.29); catalogued as rs749835352, COSV66911575; called by muse, mutect2, varscan2
- FOXK1 | c.1060C>T p.R354W | Missense Mutation (SNP) | VAF 17/25 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61064938; called by muse, mutect2, varscan2
- GSTM4 | c.282G>T p.K94N | Missense Mutation (SNP) | VAF 14/242 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.019); catalogued as rs200306410; called by muse, mutect2
- H1-3 | c.571G>C p.A191P | Missense Mutation (SNP) | VAF 49/98 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.147); catalogued as rs757600151, COSV55097839; called by muse, varscan2
- H2BC12 | c.108G>C p.E36D | Missense Mutation (SNP) | VAF 51/130 reads (39%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.227); catalogued as COSV100804720; called by muse, mutect2, varscan2
- HERPUD1 | c.529T>C p.Y177H | Missense Mutation (SNP) | VAF 35/36 reads (97%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs766342067; called by muse, mutect2, varscan2
- HEXA | c.436G>A p.V146I | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT tolerated (0.68); PolyPhen benign (0.024); catalogued as CD920868; called by muse, mutect2, varscan2
- HFM1 | c.4163dup p.N1388Kfs*8 | Frame Shift Ins (INS) | VAF 26/68 reads (38%) | catalogued as rs759278255, COSV99646600; called by mutect2, varscan2
- HS3ST3B1 | c.472C>T p.R158C | Missense Mutation (SNP) | VAF 17/113 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62906112; called by muse, mutect2, varscan2
- IGFBP6 | c.383G>A p.R128H | Missense Mutation (SNP) | VAF 73/160 reads (46%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.851); catalogued as rs757264943; called by muse, mutect2, varscan2
- IGHA1 | c.611G>C p.C204S | Missense Mutation (SNP) | VAF 49/120 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766025541; called by muse, mutect2, varscan2
- IGHJ6 | c.28T>A p.W10R | Missense Mutation (SNP) | VAF 40/40 reads (100%) | PolyPhen probably damaging (0.996); catalogued as rs371901248; called by muse, mutect2
- IGHV2-70 | c.83C>G p.P28R | Missense Mutation (SNP) | VAF 40/53 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770314362; called by muse, varscan2
- IGLC3 | c.252C>G p.S84R | Missense Mutation (SNP) | VAF 52/93 reads (56%) | PolyPhen benign (0.042); catalogued as rs1448550991; called by muse, mutect2, varscan2
- IGLV4-60 | c.272G>A p.S91N | Missense Mutation (SNP) | VAF 89/187 reads (48%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.448); catalogued as rs187948661; called by muse, varscan2
- IGLV4-69 | c.151T>G p.Y51D | Missense Mutation (SNP) | VAF 62/154 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.297); catalogued as rs55676710; called by muse, varscan2
- KCNK18 | c.895G>T p.A299S | Missense Mutation (SNP) | VAF 138/312 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); catalogued as rs1487757211; called by muse, mutect2, varscan2
- KIF19 | c.637G>A p.A213T | Missense Mutation (SNP) | VAF 34/69 reads (49%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.642); catalogued as rs144185563; called by muse, mutect2, varscan2
- LAMB2 | c.4522G>A p.A1508T | Missense Mutation (SNP) | VAF 13/166 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.194); catalogued as COSV59736124; called by muse, mutect2
- NCKAP5 | c.5173T>G p.F1725V | Missense Mutation (SNP) | VAF 54/106 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1217857257; called by muse, mutect2, varscan2
- NLRP3 | c.493C>T p.R165C | Missense Mutation (SNP) | VAF 87/141 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs141906483; called by muse, mutect2, varscan2
- NOA1 | c.2045C>T p.P682L | Missense Mutation (SNP) | VAF 63/168 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.286); catalogued as rs750105041; called by muse, mutect2, varscan2
- PANX2 | c.787G>A p.A263T | Missense Mutation (SNP) | VAF 79/176 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.195); catalogued as rs778681291, COSV99347902; called by muse, mutect2, varscan2
- PCDH10 | c.164C>T p.T55M | Missense Mutation (SNP) | VAF 70/145 reads (48%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.845); catalogued as rs199719551, COSV52090301; called by muse, mutect2, varscan2
- PCDHA5 | c.1249G>A p.V417M | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.483); catalogued as rs999470777, COSV65349874, COSV65353767, COSV65355774; called by muse, mutect2, varscan2
- PI3 | c.250G>A p.A84T | Missense Mutation (SNP) | VAF 78/184 reads (42%) | SIFT tolerated (0.36); PolyPhen benign (0.188); catalogued as rs780306943, COSV54783016, COSV54783391; called by muse, mutect2, varscan2
- PIK3R6 | c.1249C>T p.R417W | Missense Mutation (SNP) | VAF 42/79 reads (53%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs766884110; called by muse, mutect2, varscan2
- SLC25A45 | c.682C>T p.R228W | Missense Mutation (SNP) | VAF 116/245 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs559396610; called by muse, mutect2, varscan2
- SLC4A8 | c.2833C>T p.R945W | Missense Mutation (SNP) | VAF 57/127 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781277225; called by muse, mutect2, varscan2
- STAC | c.1196T>C p.L399P | Missense Mutation (SNP) | VAF 38/462 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56216287; called by muse, mutect2
- TBX22 | c.116A>G p.K39R | Missense Mutation (SNP) | VAF 40/40 reads (100%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV100960884; called by muse, mutect2, varscan2
- TNS1 | c.442C>T p.R148W | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs750588464, COSV50691569; called by muse, mutect2, varscan2
- TSPAN10 | c.472C>T p.P158S (on ENST00000574882 / NM_001290212.1; = p.P120S on NM_031945.4) | Missense Mutation (SNP) | VAF 53/135 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as rs376783183; called by muse, mutect2, varscan2
- UBXN6 | c.859G>A p.E287K | Missense Mutation (SNP) | VAF 80/176 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.322); catalogued as rs549874491, COSV56671263; called by muse, mutect2, varscan2
- ZBTB39 | c.343C>T p.L115F | Missense Mutation (SNP) | VAF 93/183 reads (51%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.958); catalogued as COSV55627905; called by muse, mutect2, varscan2
- ZNF418 | c.1255G>A p.G419S | Missense Mutation (SNP) | VAF 31/225 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV101268934; called by muse, mutect2, varscan2
- ABCG2 | c.1005T>G p.I335M | Missense Mutation (SNP) | VAF 56/120 reads (47%) | SIFT tolerated (0.27); PolyPhen benign (0.003); called by muse, varscan2
- ACTB | c.122A>G p.Q41R | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.317); called by muse, mutect2, varscan2
- ACTG1 | c.917A>G p.Y306C | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ACTG1 | c.29T>A p.I10N | Missense Mutation (SNP) | VAF 127/253 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.557); called by muse, mutect2, varscan2
- ADAMTSL4 | c.2575G>A p.G859R | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ANAPC7 | c.784G>T p.E262* | Nonsense Mutation (SNP) | VAF 28/368 reads (8%) | called by muse, mutect2
- ATP10A | c.2227G>T p.D743Y | Missense Mutation (SNP) | VAF 160/347 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- BHLHE23 | c.568A>T p.T190S (on ENST00000370346; = p.T206S on NM_080606.4) | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT tolerated (0.15); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.3790G>C p.D1264H | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- C9orf152 | c.397G>T p.D133Y | Missense Mutation (SNP) | VAF 103/237 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.66); called by muse, mutect2
- CD36 | c.486T>G p.I162M | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.89); called by muse, mutect2, varscan2
- CELF2 | c.250+1del | Frame Shift Del (DEL) | VAF 38/80 reads (48%) | called by mutect2, varscan2
- CHD2 | c.1052+1G>C p.X351_splice | Splice Site (SNP) | VAF 47/103 reads (46%) | called by muse, mutect2, varscan2
- DDX53 | c.1208C>A p.T403N | Missense Mutation (SNP) | VAF 100/102 reads (98%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DNAAF2 | c.1477G>A p.E493K | Missense Mutation (SNP) | VAF 56/115 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- DSC1 | c.1198A>G p.N400D | Missense Mutation (SNP) | VAF 27/53 reads (51%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DST | c.4222A>T p.T1408S (on ENST00000361203 / NM_001374722.1; = p.T1082S on NM_001723.6) | Missense Mutation (SNP) | VAF 112/235 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- DTX1 | c.194T>G p.V65G | Missense Mutation (SNP) | VAF 32/51 reads (63%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FBN2 | c.8209A>G p.M2737V | Missense Mutation (SNP) | VAF 51/138 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- GGA3 | c.731A>T p.D244V (on ENST00000537686 / NM_138619.4; = p.D211V on NM_014001.5) | Missense Mutation (SNP) | VAF 32/71 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- H1-3 | c.480G>C p.K160N | Missense Mutation (SNP) | VAF 40/91 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.439); called by muse, varscan2
- HECW2 | c.2022T>A p.F674L | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- HTR7 | c.994A>G p.I332V | Missense Mutation (SNP) | VAF 92/172 reads (53%) | SIFT tolerated (0.14); PolyPhen benign (0.152); called by muse, mutect2, varscan2
- IFT172 | c.1955G>A p.G652D | Missense Mutation (SNP) | VAF 65/179 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- IGHA1 | c.847_862del p.Q283Afs*7 | Frame Shift Del (DEL) | VAF 32/122 reads (26%) | called by mutect2, varscan2
- IGHG2 | c.315_324del p.E105Dfs*24 | Frame Shift Del (DEL) | VAF 36/100 reads (36%) | called by mutect2, pindel*, varscan2*
- IGLV3-19 | c.59C>G p.S20C | Missense Mutation (SNP) | VAF 22/24 reads (92%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, varscan2
- IRAK1 | c.1033A>C p.N345H | Missense Mutation (SNP) | VAF 21/22 reads (95%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ITGA1 | c.2771+2T>C p.X924_splice | Splice Site (SNP) | VAF 29/73 reads (40%) | called by muse, mutect2, varscan2
- KNL1 | c.4907T>A p.I1636K (on ENST00000346991 / NM_170589.5; = p.I1610K on NM_144508.5) | Missense Mutation (SNP) | VAF 54/122 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- MPRIP | c.1124G>A p.R375K | Missense Mutation (SNP) | VAF 15/167 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.952); called by muse, mutect2
- MUC4 | c.1672del p.T558Qfs*29 | Frame Shift Del (DEL) | VAF 40/133 reads (30%) | called by mutect2, pindel, varscan2
- NPTX2 | c.733C>T p.P245S | Missense Mutation (SNP) | VAF 97/194 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR51A2 | c.24T>G p.Y8* | Nonsense Mutation (SNP) | VAF 93/196 reads (47%) | called by muse, mutect2, varscan2
- PCDHGC3 | c.635T>A p.L212* | Nonsense Mutation (SNP) | VAF 11/200 reads (6%) | called by muse, mutect2
- RAB8A | c.481-2A>G p.X161_splice | Splice Site (SNP) | VAF 25/58 reads (43%) | called by muse, mutect2, varscan2
- RASL11B | c.544T>C p.S182P | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- RNF180 | c.1726G>A p.V576I | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT tolerated (0.55); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- RYR2 | c.2492A>C p.K831T | Missense Mutation (SNP) | VAF 93/317 reads (29%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.714); called by muse, mutect2, varscan2
- SCCPDH | c.14_19del p.Q5_R6del | In Frame Del (DEL) | VAF 25/62 reads (40%) | called by mutect2, pindel, varscan2
- SLAIN2 | c.1406T>C p.L469S | Missense Mutation (SNP) | VAF 21/339 reads (6%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); called by muse, mutect2
- SLCO6A1 | c.1400T>A p.I467K | Missense Mutation (SNP) | VAF 27/54 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); called by muse, varscan2
- SLITRK5 | c.2485C>T p.R829W | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- SOX6 | c.1199C>A p.P400H (on ENST00000528429 / NM_001145819.2; = p.P359H on NM_017508.3) | Missense Mutation (SNP) | VAF 41/103 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.414); called by muse, mutect2, varscan2
- TBC1D16 | c.803G>A p.G268D | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT tolerated (0.5); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- TCP11 | c.649C>A p.H217N (on ENST00000512012; = p.H155N on NM_018679.5) | Missense Mutation (SNP) | VAF 62/132 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.331); called by muse, mutect2, varscan2
- TMEM232 | c.796T>C p.W266R | Missense Mutation (SNP) | VAF 55/333 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TOX | c.102+2T>C p.X34_splice | Splice Site (SNP) | VAF 45/78 reads (58%) | called by muse, mutect2, varscan2
- TRPA1 | c.8G>A p.R3H | Missense Mutation (SNP) | VAF 15/25 reads (60%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.441); called by muse, mutect2, varscan2
- TSHR | c.323T>G p.I108S | Missense Mutation (SNP) | VAF 57/121 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- USP25 | c.2068G>A p.E690K | Missense Mutation (SNP) | VAF 15/197 reads (8%) | SIFT tolerated (0.58); PolyPhen benign (0); called by muse, mutect2
- USP7 | c.1855C>T p.Q619* | Nonsense Mutation (SNP) | VAF 22/44 reads (50%) | called by muse, mutect2, varscan2
- ZFP36L1 | c.56del p.K19Rfs*61 | Frame Shift Del (DEL) | VAF 40/112 reads (36%) | called by pindel, varscan2
- ARFGEF3 | c.4509C>T p.L1503= | Silent (SNP) | VAF 36/67 reads (54%) | called by muse, mutect2, varscan2
- ATM | c.7485T>C p.S2495= | Silent (SNP) | VAF 112/211 reads (53%) | called by muse, mutect2, varscan2
- DNAJC7 | c.666C>T p.Y222= | Silent (SNP) | VAF 39/95 reads (41%) | catalogued as rs782348244, COSV57269737; called by muse, mutect2, varscan2
- GK2 | c.1260T>C p.R420= | Silent (SNP) | VAF 44/97 reads (45%) | called by muse, mutect2, varscan2
- GPR108 | c.45G>T p.A15= | Silent (SNP) | VAF 112/218 reads (51%) | called by muse, mutect2
- GRM8 | c.2400C>A p.I800= | Silent (SNP) | VAF 13/159 reads (8%) | called by muse, mutect2
- HAPLN4 | c.609C>T p.R203= | Silent (SNP) | VAF 53/101 reads (52%) | catalogued as rs1213293720; called by muse, mutect2, varscan2
- IGHA1 | c.742C>T p.L248= | Silent (SNP) | VAF 29/87 reads (33%) | catalogued as rs201246460; called by muse, mutect2, varscan2
- IGHG2 | c.438C>T p.S146= | Silent (SNP) | VAF 30/56 reads (54%) | called by muse, mutect2, varscan2
- IGKV2-28 | c.168C>T p.N56= | Silent (SNP) | VAF 6/12 reads (50%) | catalogued as rs745707678; called by mutect2, varscan2
- LEMD3 | c.741C>T p.S247= | Silent (SNP) | VAF 105/219 reads (48%) | called by muse, mutect2, varscan2
- MAGEC2 | c.9C>T p.P3= | Silent (SNP) | VAF 71/74 reads (96%) | catalogued as rs753358068, COSV56001142; called by muse, mutect2, varscan2
- MRPS11 | c.465G>A p.G155= | Silent (SNP) | VAF 54/97 reads (56%) | catalogued as COSV100363678; called by muse, mutect2, varscan2
- NCOA3 | c.2913G>A p.A971= | Silent (SNP) | VAF 40/93 reads (43%) | catalogued as rs767740617; called by muse, mutect2, varscan2
- NLRP9 | c.1776G>A p.T592= | Silent (SNP) | VAF 33/65 reads (51%) | catalogued as rs750216746, COSV60462686; called by muse, mutect2, varscan2
- PCDHA3 | c.387C>T p.N129= | Silent (SNP) | VAF 32/67 reads (48%) | catalogued as rs1554121552, COSV65365560; called by muse, mutect2, varscan2
- PTGFR | c.507G>T p.L169= | Silent (SNP) | VAF 59/152 reads (39%) | called by muse, mutect2, varscan2
- PTPRN2 | c.1407G>A p.A469= | Silent (SNP) | VAF 87/154 reads (56%) | catalogued as rs765722971, COSV67023396; called by muse, mutect2, varscan2
- REN | c.216C>T p.T72= | Silent (SNP) | VAF 41/161 reads (25%) | catalogued as rs774619132; called by muse, mutect2, varscan2
- SACS | c.4455T>C p.A1485= | Silent (SNP) | VAF 73/153 reads (48%) | called by muse, mutect2, varscan2
- SIPA1L2 | c.2742C>T p.Y914= | Silent (SNP) | VAF 259/376 reads (69%) | catalogued as rs1270016339; called by muse, mutect2, varscan2
- SLCO6A1 | c.1332T>G p.V444= | Silent (SNP) | VAF 45/103 reads (44%) | called by muse, varscan2
- SMARCA2 | c.2839C>T p.L947= | Silent (SNP) | VAF 42/85 reads (49%) | called by muse, mutect2, varscan2
- TRDN | c.918A>G p.S306= | Silent (SNP) | VAF 19/37 reads (51%) | called by muse, mutect2, varscan2
- TRMT10C | c.927T>C p.I309= | Silent (SNP) | VAF 75/135 reads (56%) | called by muse, mutect2, varscan2
- TUT7 | c.2316T>C p.H772= | Silent (SNP) | VAF 123/258 reads (48%) | called by muse, mutect2, varscan2
- UBR2 | c.4845C>T p.S1615= | Silent (SNP) | VAF 59/127 reads (46%) | catalogued as COSV65753152; called by muse, mutect2, varscan2
- ZSWIM8 | c.5355C>T p.D1785= (on ENST00000605216 / NM_001242487.2; = p.D1790= on NM_015037.3) | Silent (SNP) | VAF 98/219 reads (45%) | catalogued as rs771281686, COSV55218716; called by muse, mutect2, varscan2
- AC007405.3 | n.900G>A | RNA (SNP) | VAF 20/41 reads (49%) | called by muse, mutect2, varscan2
- AC131160.1 | c.*331G>C | 3'UTR (SNP) | VAF 24/57 reads (42%) | called by muse, mutect2, varscan2
- AC134878.2 | n.1202C>A | RNA (SNP) | VAF 69/71 reads (97%) | called by muse, mutect2, varscan2
- ACTB | c.-16A>G | 5'UTR (SNP) | VAF 31/62 reads (50%) | catalogued as rs201258445; called by muse, varscan2
- ACTRT2 | c.-15G>A | 5'UTR (SNP) | VAF 29/68 reads (43%) | called by muse, mutect2, varscan2
- AFF3 | c.*144G>A | 3'UTR (SNP) | VAF 29/64 reads (45%) | called by muse, mutect2, varscan2
- AGK | c.*1440A>G | 3'UTR (SNP) | VAF 29/54 reads (54%) | called by muse, mutect2, varscan2
- AL353572.2 | n.678C>T | RNA (SNP) | VAF 8/17 reads (47%) | called by muse, mutect2, varscan2
- AL592490.1 | c.*149A>G | 3'UTR (SNP) | VAF 35/78 reads (45%) | called by muse, mutect2, varscan2
- ANKS6 | c.*2084G>A | 3'UTR (SNP) | VAF 32/53 reads (60%) | called by muse, mutect2, varscan2
- AP000769.5 | chr11:65497981 A>C | 5'Flank (SNP) | VAF 100/170 reads (59%) | catalogued as rs553137490; called by muse, mutect2, varscan2
- AQP11 | c.*757A>C | 3'UTR (SNP) | VAF 29/65 reads (45%) | called by muse, mutect2, varscan2
- ARHGAP29 | c.*1205A>C | 3'UTR (SNP) | VAF 14/33 reads (42%) | called by muse, mutect2, varscan2
- ARSD | c.439+82G>A | Intron (SNP) | VAF 44/46 reads (96%) | catalogued as rs763868569, COSV54200968; called by muse, mutect2, varscan2
- ATP5F1A | c.1284+62A>C | Intron (SNP) | VAF 19/51 reads (37%) | called by muse, mutect2, varscan2
- AURKC | chr19:57230999 G>A | 5'Flank (SNP) | VAF 8/20 reads (40%) | called by muse, mutect2
- BCL7A | chr12:122021167 C>A | 5'Flank (SNP) | VAF 65/144 reads (45%) | called by muse, varscan2
- BCL7A | chr12:122021275 C>G | 5'Flank (SNP) | VAF 68/138 reads (49%) | catalogued as COSV55847946, COSV55851575; called by muse, varscan2
- CANX | c.1399-128A>T | Intron (SNP) | VAF 12/22 reads (55%) | called by muse, mutect2, varscan2
- CCDC185 | c.-16G>A | 5'UTR (SNP) | VAF 9/32 reads (28%) | called by muse, mutect2, varscan2
- CCDC62 | c.*59A>C | 3'UTR (SNP) | VAF 55/146 reads (38%) | called by muse, mutect2, varscan2
- CCSER1 | c.2010+3237A>C | Intron (SNP) | VAF 30/59 reads (51%) | called by muse, varscan2
- CHRNA1 | chr2:174747640 C>A | 3'Flank (SNP) | VAF 41/77 reads (53%) | called by muse, mutect2, varscan2
- CPA4 | c.*267G>A | 3'UTR (SNP) | VAF 58/115 reads (50%) | catalogued as rs570566291; called by muse, mutect2, varscan2
- CPQ | c.-17A>G | 5'UTR (SNP) | VAF 86/198 reads (43%) | called by muse, mutect2, varscan2
- CSNK1G3 | chr5:123615620 C>T | 3'Flank (SNP) | VAF 10/188 reads (5%) | called by muse, mutect2
- CYBB | c.*1574T>G | 3'UTR (SNP) | VAF 18/18 reads (100%) | called by muse, mutect2, varscan2
- DEPDC1 | c.*1156C>A | 3'UTR (SNP) | VAF 163/316 reads (52%) | called by muse, mutect2, varscan2
- DIAPH3 | c.*759T>A | 3'UTR (SNP) | VAF 31/82 reads (38%) | called by muse, mutect2, varscan2
- DPPA4 | c.*1513del | 3'UTR (DEL) | VAF 34/90 reads (38%) | called by mutect2, pindel, varscan2
- EFCAB5 | c.2581-18A>G | Intron (SNP) | VAF 25/50 reads (50%) | called by muse, mutect2, varscan2
- EFR3A | c.*1647G>C | 3'UTR (SNP) | VAF 10/76 reads (13%) | called by muse, mutect2, varscan2
- EGFLAM | chr5:38465124 ins G | 3'Flank (INS) | VAF 6/14 reads (43%) | called by mutect2, varscan2
- EIF1B | chr3:40309530 C>A | 5'Flank (SNP) | VAF 14/28 reads (50%) | called by muse, mutect2
- ESS2 | c.*3156G>A | 3'UTR (SNP) | VAF 85/157 reads (54%) | called by muse, mutect2, varscan2
- ETV1 | chr7:13894363 A>C | 3'Flank (SNP) | VAF 47/85 reads (55%) | called by muse, mutect2, varscan2
- EVA1A | c.*898del | 3'UTR (DEL) | VAF 52/125 reads (42%) | called by mutect2, pindel, varscan2
- EXT2 | c.*773G>A | 3'UTR (SNP) | VAF 56/124 reads (45%) | called by muse, mutect2, varscan2
- FAM193B | c.1275+1119C>T | Intron (SNP) | VAF 17/234 reads (7%) | catalogued as rs776564548, COSV61559674; called by muse, mutect2
- FAM76A | c.837+351G>A | Intron (SNP) | VAF 23/50 reads (46%) | catalogued as rs904529908; called by muse, mutect2, varscan2
- FBN2 | c.*1142G>A | 3'UTR (SNP) | VAF 36/70 reads (51%) | called by muse, mutect2, varscan2
- FBXL7 | c.-49G>A | 5'UTR (SNP) | VAF 77/137 reads (56%) | catalogued as rs766343857, COSV101554478; called by muse, mutect2, varscan2
- GABRG2 | c.752-100C>A | Intron (SNP) | VAF 17/44 reads (39%) | called by muse, mutect2, varscan2
- GABRG2 | c.1249-1427del | Intron (DEL) | VAF 26/44 reads (59%) | catalogued as rs912927082; called by mutect2, varscan2
- GCSAM | c.*2468A>C | 3'UTR (SNP) | VAF 59/124 reads (48%) | called by muse, mutect2, varscan2
- GDF10 | c.*437dup | 3'UTR (INS) | VAF 32/82 reads (39%) | called by mutect2, varscan2
- GDF7 | c.*79G>A | 3'UTR (SNP) | VAF 22/45 reads (49%) | called by muse, mutect2, varscan2
- GINS4 | c.*2390A>C | 3'UTR (SNP) | VAF 118/127 reads (93%) | called by muse, mutect2, varscan2
- GRIPAP1 | c.2061+28C>T | Intron (SNP) | VAF 69/69 reads (100%) | called by muse, mutect2, varscan2
- GXYLT1 | c.-87C>T | 5'UTR (SNP) | VAF 12/28 reads (43%) | catalogued as rs975467717; called by muse, mutect2, varscan2
- H2BC15 | chr6:27837925 G>C | 5'Flank (SNP) | VAF 164/352 reads (47%) | called by muse, mutect2, varscan2
- HADH | c.710-104T>A | Intron (SNP) | VAF 33/76 reads (43%) | catalogued as rs373586794, COSV58847670; called by mutect2, varscan2
- HEPACAM | chr11:124936359 G>T | 5'Flank (SNP) | VAF 29/68 reads (43%) | called by muse, mutect2, varscan2
- HSP90AA4P | n.1594T>A | RNA (SNP) | VAF 106/216 reads (49%) | called by muse, mutect2, varscan2
- IGLV3-21 | c.-100T>G | 5'UTR (SNP) | VAF 24/25 reads (96%) | called by muse, mutect2, varscan2
- IL15 | c.*829C>A | 3'UTR (SNP) | VAF 14/30 reads (47%) | called by muse, varscan2
- IL15 | c.*1125T>G | 3'UTR (SNP) | VAF 30/55 reads (55%) | called by muse, mutect2, varscan2
- IL21R | c.*843A>G | 3'UTR (SNP) | VAF 49/99 reads (49%) | called by muse, mutect2, varscan2
- IL2RB | c.*751T>A | 3'UTR (SNP) | VAF 63/116 reads (54%) | called by muse, mutect2, varscan2
- INPP4B | chr4:142025326 A>G | 3'Flank (SNP) | VAF 20/71 reads (28%) | called by muse, mutect2, varscan2
- INPP5B | c.772+610G>A | Intron (SNP) | VAF 78/165 reads (47%) | called by muse, mutect2, varscan2
- INPP5E | c.1034+40T>C | Intron (SNP) | VAF 5/18 reads (28%) | called by mutect2, varscan2
- IRAK3 | c.*789T>C | 3'UTR (SNP) | VAF 19/110 reads (17%) | called by muse, mutect2, varscan2
- KCNV1 | chr8:109964959 A>G | 3'Flank (SNP) | VAF 66/143 reads (46%) | called by muse, mutect2, varscan2
- KLHDC10 | c.*2192A>G | 3'UTR (SNP) | VAF 32/71 reads (45%) | called by muse, mutect2, varscan2
- KRTAP1-1 | c.-47C>A | 5'UTR (SNP) | VAF 145/274 reads (53%) | called by muse, mutect2, varscan2
- LIMD2 | c.-45A>C | 5'UTR (SNP) | VAF 33/59 reads (56%) | called by muse, mutect2, varscan2
- LINS1 | c.*29G>T | 3'UTR (SNP) | VAF 26/69 reads (38%) | called by muse, mutect2
- LMO3 | c.*2651A>C | 3'UTR (SNP) | VAF 44/92 reads (48%) | called by muse, mutect2, varscan2
- LRBA | c.4569+3445G>C | Intron (SNP) | VAF 64/139 reads (46%) | called by muse, mutect2, varscan2
- LTB | c.163-68A>C | Intron (SNP) | VAF 193/438 reads (44%) | called by muse, varscan2
- MADD | c.*394C>A | 3'UTR (SNP) | VAF 69/142 reads (49%) | called by muse, mutect2, varscan2
- MARK3 | c.1587-875G>A | Intron (SNP) | VAF 4/10 reads (40%) | catalogued as COSV53507431; called by muse, mutect2
- MBL2 | c.*1134C>G | 3'UTR (SNP) | VAF 8/66 reads (12%) | called by muse, mutect2, varscan2
- MGAT2 | c.-339G>A | 5'UTR (SNP) | VAF 30/60 reads (50%) | called by muse, mutect2, varscan2
- MIR5195 | chr14:106851305 G>A | 5'Flank (SNP) | VAF 85/169 reads (50%) | catalogued as rs778801727; called by muse, varscan2
- MIR5195 | chr14:106851324 C>G | 5'Flank (SNP) | VAF 61/137 reads (45%) | catalogued as rs572738324; called by muse, varscan2
- MIR5195 | chr14:106851378 T>G | 5'Flank (SNP) | VAF 57/117 reads (49%) | catalogued as rs1262641008; called by muse, varscan2
- MIR5195 | chr14:106851391 G>A | 5'Flank (SNP) | VAF 54/124 reads (44%) | catalogued as rs1298140363; called by muse, varscan2
- MROH7 | c.2965-148G>A | Intron (SNP) | VAF 127/266 reads (48%) | called by muse, mutect2, varscan2
- MYO1E | c.*106C>T | 3'UTR (SNP) | VAF 31/60 reads (52%) | called by muse, mutect2, varscan2
- MYO1E | c.-175C>T | 5'UTR (SNP) | VAF 45/96 reads (47%) | called by muse, mutect2, varscan2
- NACA4P | n.535C>T | RNA (SNP) | VAF 32/55 reads (58%) | catalogued as rs1190802938; called by muse, mutect2, varscan2
- NEBL | c.*4475A>C | 3'UTR (SNP) | VAF 40/94 reads (43%) | called by muse, mutect2
- NEBL | c.*4473A>G | 3'UTR (SNP) | VAF 40/97 reads (41%) | called by muse, mutect2
- NIPBL | c.8049+25A>G | Intron (SNP) | VAF 30/50 reads (60%) | catalogued as COSV56953693; called by muse, mutect2, varscan2
- NOX5 | c.*6033G>A | 3'UTR (SNP) | VAF 54/96 reads (56%) | called by muse, mutect2, varscan2
- NR2F2 | c.-1111C>T | 5'UTR (SNP) | VAF 114/231 reads (49%) | called by muse, mutect2, varscan2
- NRBP1 | c.*368T>A | 3'UTR (SNP) | VAF 22/60 reads (37%) | called by muse, mutect2, varscan2
- NSD2 | c.*2789G>A | 3'UTR (SNP) | VAF 16/41 reads (39%) | called by muse, mutect2, varscan2
- NUBPL | c.*1491G>A | 3'UTR (SNP) | VAF 14/33 reads (42%) | called by muse, mutect2, varscan2
- OTUD3 | c.*2245G>A | 3'UTR (SNP) | VAF 40/72 reads (56%) | called by muse, mutect2, varscan2
- PCSK2 | c.-195C>T | 5'UTR (SNP) | VAF 40/78 reads (51%) | called by muse, mutect2, varscan2
- PITX2 | c.*51C>T | 3'UTR (SNP) | VAF 19/37 reads (51%) | catalogued as rs772842482, COSV100146331; called by muse, mutect2, varscan2
- PLEKHG3 | chr14:64749105 C>T | 3'Flank (SNP) | VAF 8/23 reads (35%) | catalogued as rs931508539; called by muse, mutect2, varscan2
- PLEKHM1P1 | n.614+6861A>G | Intron (SNP) | VAF 9/32 reads (28%) | called by muse, mutect2, varscan2
- PNRC2 | c.*983A>C | 3'UTR (SNP) | VAF 43/89 reads (48%) | called by muse, mutect2, varscan2
- POLM | c.969-36C>A | Intron (SNP) | VAF 17/37 reads (46%) | catalogued as rs766937371; called by muse, mutect2, varscan2
- POU3F2 | c.*1158T>A | 3'UTR (SNP) | VAF 10/29 reads (34%) | called by muse, mutect2, varscan2
- PPFIBP2 | chr11:7656806 C>T | 3'Flank (SNP) | VAF 27/62 reads (44%) | catalogued as rs1189103997; called by muse, mutect2, varscan2
- PPP1R13B | c.970-121G>T | Intron (SNP) | VAF 6/14 reads (43%) | catalogued as rs533592814; called by muse, mutect2, varscan2
- PPP3CA | chr4:101348856 G>T | 5'Flank (SNP) | VAF 66/135 reads (49%) | called by muse, mutect2, varscan2
- PPT1 | chr1:40072722 C>G | 3'Flank (SNP) | VAF 6/98 reads (6%) | called by muse, mutect2
- RAB3B | c.*7300T>C | 3'UTR (SNP) | VAF 15/31 reads (48%) | called by muse, mutect2, varscan2
- RALGPS1 | c.*4334A>C | 3'UTR (SNP) | VAF 12/17 reads (71%) | called by muse, mutect2, varscan2
- RAPGEF5 | c.*2904C>T | 3'UTR (SNP) | VAF 44/90 reads (49%) | called by muse, mutect2, varscan2
- RARRES1 | c.*622T>A | 3'UTR (SNP) | VAF 8/81 reads (10%) | called by muse, mutect2
- RASSF8 | chr12:26072396 G>A | 3'Flank (SNP) | VAF 15/31 reads (48%) | called by muse, mutect2, varscan2
- RBFOX1 | c.28-185124C>T | Intron (SNP) | VAF 48/114 reads (42%) | called by muse, mutect2, varscan2
- RBM38 | c.*136G>A | 3'UTR (SNP) | VAF 67/130 reads (52%) | catalogued as rs959862858; called by muse, mutect2
- RETREG2 | c.*2111T>G | 3'UTR (SNP) | VAF 13/36 reads (36%) | called by muse, mutect2
- RNF185 | c.*2203G>A | 3'UTR (SNP) | VAF 9/133 reads (7%) | catalogued as rs1045297299; called by muse, mutect2
- RNPC3 | c.-357C>T | 5'UTR (SNP) | VAF 41/75 reads (55%) | catalogued as rs1407169958; called by muse, varscan2
- RUNX2 | c.*607T>C | 3'UTR (SNP) | VAF 28/66 reads (42%) | called by muse, varscan2
- RUNX3 | c.*1398_*1400del | 3'UTR (DEL) | VAF 85/179 reads (47%) | called by pindel, varscan2
- S1PR2 | c.-43+722C>T | Intron (SNP) | VAF 49/118 reads (42%) | catalogued as rs571967599, COSV73912781; called by muse, mutect2, varscan2
- SECISBP2L | c.*1943A>T | 3'UTR (SNP) | VAF 43/83 reads (52%) | called by muse, mutect2, varscan2
- SEL1L3 | chr4:25863585 A>G | 5'Flank (SNP) | VAF 50/103 reads (49%) | called by muse, mutect2, varscan2
- SEMA4D | c.*1164G>T | 3'UTR (SNP) | VAF 70/137 reads (51%) | called by muse, mutect2, varscan2
- SFRP2 | c.-185C>T | 5'UTR (SNP) | VAF 7/16 reads (44%) | called by muse, mutect2, varscan2
- SLC12A2 | c.*1190T>C | 3'UTR (SNP) | VAF 25/54 reads (46%) | called by muse, mutect2, varscan2
- SLC25A43 | c.*1387G>A | 3'UTR (SNP) | VAF 20/20 reads (100%) | called by muse, mutect2, varscan2
- SMU1 | c.*4660T>C | 3'UTR (SNP) | VAF 42/79 reads (53%) | called by muse, mutect2, varscan2
- SNORD114-14 | chr14:100970019 A>C | 5'Flank (SNP) | VAF 60/126 reads (48%) | called by muse, mutect2, varscan2
- SP9 | c.21+21C>T | Intron (SNP) | VAF 50/100 reads (50%) | called by muse, mutect2, varscan2
- SPEF2 | c.2839+629A>C | Intron (SNP) | VAF 52/101 reads (51%) | called by muse, mutect2, varscan2
- SYT11 | c.-130A>C | 5'UTR (SNP) | VAF 66/179 reads (37%) | called by muse, mutect2, varscan2
- TBC1D4 | c.-87G>A | 5'UTR (SNP) | VAF 14/27 reads (52%) | catalogued as rs897505857; called by muse, mutect2, varscan2
- TBX2 | c.*570dup | 3'UTR (INS) | VAF 12/58 reads (21%) | catalogued as rs201339346; called by pindel, varscan2
- TBX5 | c.*1145A>C | 3'UTR (SNP) | VAF 32/63 reads (51%) | called by muse, mutect2
- THSD4 | c.*808C>A | 3'UTR (SNP) | VAF 76/155 reads (49%) | called by muse, mutect2, varscan2
- TICRR | c.*770G>A | 3'UTR (SNP) | VAF 50/101 reads (50%) | catalogued as rs1441842699, COSV51542099; called by muse, mutect2, varscan2
- TM4SF18 | c.*2527A>T | 3'UTR (SNP) | VAF 20/49 reads (41%) | called by muse, mutect2
- TMEM106B | c.*1027T>G | 3'UTR (SNP) | VAF 52/100 reads (52%) | called by muse, mutect2, varscan2
- TMEM184A | c.645-192dup | Intron (INS) | VAF 22/44 reads (50%) | catalogued as rs924879069; called by mutect2, pindel, varscan2
- TMEM250 | c.*650C>T | 3'UTR (SNP) | VAF 50/99 reads (51%) | catalogued as rs892927768; called by muse, mutect2, varscan2
- TMEM254 | c.87+86C>T | Intron (SNP) | VAF 46/107 reads (43%) | called by muse, mutect2, varscan2
- TNNI3K | c.*81C>A | 3'UTR (SNP) | VAF 18/35 reads (51%) | called by muse, mutect2, varscan2
- TOX | chr8:59119161 A>G | 5'Flank (SNP) | VAF 11/27 reads (41%) | called by muse, mutect2, varscan2
- TPST1 | c.*49A>C | 3'UTR (SNP) | VAF 63/142 reads (44%) | called by muse, mutect2, varscan2
- TPTE | c.*12C>G | 3'UTR (SNP) | VAF 55/1248 reads (4%) | called by muse, mutect2
- TRIM9 | c.*1420T>A | 3'UTR (SNP) | VAF 26/64 reads (41%) | called by muse, mutect2, varscan2
- TRIQK | c.*820T>C | 3'UTR (SNP) | VAF 31/70 reads (44%) | called by muse, mutect2, varscan2
- TRMT10B | c.*816dup | 3'UTR (INS) | VAF 4/40 reads (10%) | called by pindel, varscan2*
- TTC30A | c.*671A>C | 3'UTR (SNP) | VAF 64/160 reads (40%) | called by muse, mutect2
- TTC39A | c.1162-2572G>A | Intron (SNP) | VAF 124/256 reads (48%) | called by muse, mutect2, varscan2
- UBL4A | c.*166C>A | 3'UTR (SNP) | VAF 120/122 reads (98%) | called by muse, mutect2, varscan2
- UFM1 | c.*1670T>C | 3'UTR (SNP) | VAF 39/90 reads (43%) | called by muse, mutect2, varscan2
- Unknown | chr7:35185788 G>A | IGR (SNP) | VAF 40/70 reads (57%) | called by muse, mutect2, varscan2
- YIPF3 | c.82-106C>T | Intron (SNP) | VAF 40/102 reads (39%) | catalogued as rs781517627; called by muse, mutect2, varscan2
